Somatic mutation profile of tumor specimen TCGA-06-0649-01B (aliquot TCGA-06-0649-01B-01W-0348-08) from TCGA case TCGA-06-0649, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.4 years (26,796 days).
Specimen TCGA-06-0649-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5da4592d-39ae-4138-9896-1fb86c06de24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0649-10A (Blood Derived Normal), aliquot TCGA-06-0649-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7c6957d-567c-41e0-a3a2-7d852eabad76

The open-access MAF lists 97 somatic variants for this specimen: 73 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 23, Nonsense Mutation 4, Frame Shift Ins 4, Frame Shift Del 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 46/430 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANK2 | c.4973T>C p.V1658A | Missense Mutation (SNP) | VAF 24/303 reads (8%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV52168769; called by muse, mutect2
- ARHGAP9 | c.1706G>A p.R569K (on ENST00000393797 / NM_001319850.2; = p.R550K on NM_032496.4) | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.191); catalogued as COSV57360740, COSV99954074; called by muse, mutect2, varscan2
- ASIC2 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1338888402, COSV63295964; called by muse, mutect2, varscan2
- BRCA1 | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 104/321 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV58788412; called by muse, mutect2, varscan2
- BTNL2 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV66631059; called by muse, mutect2, varscan2
- CACNA1I | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as rs937233213, COSV60811610; called by muse, mutect2, varscan2
- CERKL | c.1565C>T p.P522L (on ENST00000339098 / NM_001030311.2; = p.P496L on NM_201548.5) | Missense Mutation (SNP) | VAF 19/410 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV100184096; called by muse, mutect2
- CGA | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 141/358 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs145503313; called by muse, mutect2, varscan2
- CLOCK | c.416C>A p.T139N | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs766067893, COSV59401406; called by muse, mutect2, varscan2
- COL6A3 | c.3280G>A p.A1094T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs369460632, COSV55086518; called by muse, mutect2, varscan2
- CSTF2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as COSV63376203; called by muse, mutect2, varscan2
- DDX53 | c.1278G>T p.M426I | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.998); catalogued as COSV60068857; called by muse, mutect2, varscan2
- DGCR2 | c.724C>G p.P242A | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV54218025; called by muse, mutect2, varscan2
- DOK6 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.749); catalogued as rs771061011, COSV66929502; called by muse, mutect2, varscan2
- EBPL | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs775942626, COSV54432064; called by muse, mutect2, varscan2
- EGFR | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV51791901, COSV51809481; called by muse, mutect2, varscan2
- ERCC6 | c.4075A>G p.K1359E | Missense Mutation (SNP) | VAF 149/257 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs776383043, COSV63389260; called by muse, mutect2, varscan2
- F8 | c.344T>A p.V115D | Missense Mutation (SNP) | VAF 135/402 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as CM080311, CM123887, COSV64272131; called by muse, mutect2, varscan2
- FBXL5 | c.842A>C p.E281A | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV58010532; called by muse, mutect2, varscan2
- FURIN | c.1861dup p.Q621Pfs*8 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | catalogued as rs772193599; called by pindel, varscan2
- GUCY2C | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 19/68 reads (28%) | catalogued as rs760164631, COSV53789167; called by muse, mutect2, varscan2
- HEPACAM2 | c.248C>T p.S83F (on ENST00000394468 / NM_001039372.4; = p.S71F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.145); catalogued as COSV59059651; called by muse, mutect2, varscan2
- HTR7 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs768133205, COSV53285537; called by muse, mutect2, varscan2
- KLRG1 | c.170del p.Q57Rfs*24 | Frame Shift Del (DEL) | VAF 107/368 reads (29%) | catalogued as COSV56943140; called by mutect2, pindel, varscan2
- KRT222 | c.764T>G p.L255* | Nonsense Mutation (SNP) | VAF 28/114 reads (25%) | catalogued as rs1038137042, COSV67498088; called by muse, mutect2, varscan2
- LAMA2 | c.8230C>T p.P2744S | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.105); catalogued as COSV70350491; called by muse, mutect2, varscan2
- LBR | c.1274G>A p.S425N | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.808); catalogued as COSV55289602; called by muse, mutect2
- MGAT5B | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV56931118; called by muse, mutect2, varscan2
- MMP20 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs141875245; called by muse, varscan2
- MUC16 | c.6719C>A p.P2240H | Missense Mutation (SNP) | VAF 36/461 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101200266; called by muse, mutect2
- MYH3 | c.249dup p.K84Qfs*16 | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | catalogued as rs761123152; called by mutect2, varscan2
- NKD1 | c.862dup p.R288Pfs*12 | Frame Shift Ins (INS) | VAF 8/43 reads (19%) | catalogued as rs772439983; called by mutect2, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 24/140 reads (17%) | catalogued as rs754860965; called by mutect2, varscan2
- OR2B3 | c.195T>A p.N65K | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV65851027; called by muse, mutect2
- PCDH15 | c.4870C>T p.P1624S | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV57334063; called by muse, mutect2, varscan2
- PCSK5 | c.5131C>A p.P1711T | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.036); catalogued as COSV70450505; called by muse, mutect2, varscan2
- PDE1C | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 210/748 reads (28%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs746042793, COSV58510753; called by muse, mutect2, varscan2
- PEG3 | c.160T>A p.Y54N | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55637545; called by muse, mutect2
- PIM2 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV50234819; called by mutect2, varscan2
- PLG | c.143A>G p.E48G | Missense Mutation (SNP) | VAF 143/313 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV51982143; called by muse, mutect2
- PTCH2 | c.113C>G p.A38G | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64710768; called by muse, mutect2, varscan2
- PTH2R | c.616G>C p.G206R | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as rs1419275989, COSV55915463, COSV55920350; called by muse, mutect2, varscan2
- RFC4 | c.824_826del p.D275del | In Frame Del (DEL) | VAF 126/419 reads (30%) | catalogued as rs769831210; called by mutect2, pindel, varscan2
- RXRA | c.746A>T p.Y249F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV62684104; called by muse, mutect2, varscan2
- SAMD9L | c.3985A>G p.R1329G | Missense Mutation (SNP) | VAF 107/504 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59080873; called by muse, mutect2, varscan2
- SCN1A | c.5629G>C p.G1877R (on ENST00000303395 / NM_001202435.3; = p.G1866R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349267882, COSV57676252; called by muse, mutect2, varscan2
- SERPINA3 | c.770A>T p.E257V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV67585894; called by muse, mutect2, varscan2
- SLAMF8 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as rs766523263, COSV56988157; called by muse, mutect2, varscan2
- SLC25A14 | c.955C>A p.Q319K | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV54417717; called by muse, mutect2, varscan2
- SLC9A2 | c.2147C>A p.P716Q | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52131044; called by muse, varscan2
- SMARCA2 | c.3292G>A p.G1098S | Missense Mutation (SNP) | VAF 179/346 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61806538; called by muse, mutect2, varscan2
- SOAT1 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 274/896 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV62653778; called by muse, mutect2, varscan2
- TCN1 | c.351C>A p.H117Q | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV57253492; called by muse, mutect2, varscan2
- TGFBR2 | c.314A>T p.K105M | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.163); catalogued as COSV55452224; called by muse, mutect2
- TINF2 | c.1277G>A p.C426Y | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV57468661; called by muse, mutect2, varscan2
- TRAPPC8 | c.2884G>A p.G962S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV51969721; called by muse, mutect2, varscan2
- TRPM8 | c.1436A>G p.E479G | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61222105, COSV61222528; called by muse, mutect2
- TTN | c.98101G>A p.D32701N (on ENST00000591111; = p.D25277N on NM_003319.4) | Missense Mutation (SNP) | VAF 23/235 reads (10%) | PolyPhen possibly damaging (0.856); catalogued as COSV59939720; called by muse, mutect2
- UBE2NL | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 104/330 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs781838711; called by muse, varscan2
- UGGT1 | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 64/291 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52134793; called by muse, mutect2, varscan2
- UGT2B4 | c.1130C>A p.A377D | Missense Mutation (SNP) | VAF 166/476 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV59316631; called by muse, mutect2, varscan2
- UGT2B7 | c.404A>T p.K135I | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV59442934; called by muse, mutect2, varscan2
- UMODL1 | c.1031T>G p.V344G | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV61159828; called by muse, mutect2, varscan2
- ZBTB25 | c.1052G>A p.C351Y | Missense Mutation (SNP) | VAF 83/163 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759665443, COSV67198524; called by muse, mutect2, varscan2
- ZNF28 | c.1896G>C p.E632D | Missense Mutation (SNP) | VAF 501/1576 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV60422719, COSV60422841; called by muse, mutect2, varscan2
- ZNF28 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 283/666 reads (42%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100354900, COSV60422847; called by muse, varscan2
- ZNF28 | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 322/701 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV60422853; called by muse, varscan2
- DOCK9 | c.3067C>G p.H1023D (on ENST00000376460 / NM_001366676.2; = p.H1024D on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/494 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- KPNA6 | c.130_134del p.E44Tfs*4 | Frame Shift Del (DEL) | VAF 56/274 reads (20%) | called by mutect2, pindel, varscan2
- PDK3 | c.1214A>G p.K405R | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.022); called by muse, mutect2
- PRDM10 | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE2NL | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 120/322 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.094); called by muse, varscan2
- AFAP1L2 | c.1629C>T p.V543= | Silent (SNP) | VAF 76/146 reads (52%) | catalogued as COSV58413976; called by muse, mutect2, varscan2
- ATRNL1 | c.4008T>G p.P1336= | Silent (SNP) | VAF 60/132 reads (45%) | catalogued as COSV58083460, COSV58094756; called by muse, varscan2
- C3 | c.4950C>T p.G1650= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as rs757774081, COSV55571624; called by muse, mutect2, varscan2
- CACNA1F | c.1476G>A p.L492= | Silent (SNP) | VAF 74/177 reads (42%) | catalogued as COSV59904038; called by muse, mutect2, varscan2
- CATSPERG | c.3237C>T p.G1079= | Silent (SNP) | VAF 37/207 reads (18%) | catalogued as COSV53049857; called by muse, mutect2, varscan2
- CDK12 | c.4107C>T p.T1369= (on ENST00000447079 / NM_016507.4; = p.T1360= on NM_015083.3) | Silent (SNP) | VAF 44/215 reads (20%) | catalogued as rs1291511673, COSV71000268; called by muse, mutect2, varscan2
- CTNND2 | c.1758C>T p.A586= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs765074687, COSV100480785, COSV58898326; called by muse, varscan2
- CXADR | c.768C>T p.I256= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV53028752; called by muse, mutect2, varscan2
- CYLD | c.291A>G p.T97= | Silent (SNP) | VAF 103/278 reads (37%) | catalogued as COSV61094079; called by muse, mutect2, varscan2
- FOXO3 | c.672G>A p.Q224= | Silent (SNP) | VAF 152/451 reads (34%) | catalogued as COSV100670329, COSV59627617; called by muse, mutect2, varscan2
- GIMAP4 | c.633C>T p.R211= | Silent (SNP) | VAF 110/352 reads (31%) | catalogued as rs1357201397, COSV55431998; called by muse, mutect2, varscan2
- HMCN1 | c.12006C>T p.N4002= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs758672862, COSV54893270, COSV99624247; called by muse, mutect2, varscan2
- KLHL40 | c.1239C>T p.S413= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV55133983; called by muse, mutect2
- KPNA2 | c.189G>A p.P63= | Silent (SNP) | VAF 108/219 reads (49%) | catalogued as rs782745827, COSV57857337; called by muse, mutect2, varscan2
- LAMB4 | c.1743T>G p.V581= | Silent (SNP) | VAF 19/238 reads (8%) | catalogued as COSV52722278; called by muse, mutect2
- MORC1 | c.253C>A p.R85= | Silent (SNP) | VAF 38/538 reads (7%) | catalogued as COSV51714995, COSV51722623; called by muse, mutect2
- MRI1 | c.519G>C p.L173= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV50004156; called by muse, mutect2, varscan2
- NLRP7 | c.1953G>A p.P651= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as rs370874996, COSV60171329; called by muse, mutect2, varscan2
- OR5I1 | c.612C>T p.Y204= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs774747525, COSV56886443; called by muse, mutect2, varscan2
- PZP | c.1461G>A p.S487= | Silent (SNP) | VAF 38/587 reads (6%) | catalogued as rs374450463; called by muse, mutect2
- SPANXN3 | c.216G>A p.Q72= | Silent (SNP) | VAF 477/1677 reads (28%) | catalogued as COSV65140219; called by muse, mutect2, varscan2
- TADA3 | c.537C>T p.P179= | Silent (SNP) | VAF 11/198 reads (6%) | called by muse, mutect2
- TRPM6 | c.3639T>C p.D1213= | Silent (SNP) | VAF 61/165 reads (37%) | catalogued as COSV62507653; called by muse, mutect2, varscan2
- SPATA8 | n.724C>T | RNA (SNP) | VAF 6/58 reads (10%) | catalogued as rs756443854, COSV60704385; called by muse, mutect2
